Somatic mutation profile of tumor specimen TCGA-60-2725-01A (aliquot TCGA-60-2725-01A-01D-1267-08) from TCGA case TCGA-60-2725, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 74.1 years (27,073 days).
Specimen TCGA-60-2725-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f9c8343-b032-443e-a9ff-d3298f171bad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2725-11A (Solid Tissue Normal), aliquot TCGA-60-2725-11A-01D-1267-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77b7d96d-8e37-42d2-81bb-cbae37d416c9

The open-access MAF lists 144 somatic variants for this specimen: 107 protein-altering or splice-affecting, 35 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 35, Frame Shift Del 4, Nonsense Mutation 3, Splice Site 3, Splice Region 3, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC12 | c.1516G>T p.G506W | Missense Mutation (SNP) | VAF 83/401 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60912676, COSV60918835; called by muse, mutect2, varscan2
- ABCG8 | c.462C>A p.H154Q | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1325379182, COSV55391597; called by muse, mutect2, varscan2
- ABL2 | c.2632G>T p.G878W (on ENST00000502732 / NM_007314.4; = p.G863W on NM_005158.5) | Missense Mutation (SNP) | VAF 42/228 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV61012229; called by muse, mutect2, varscan2
- ACSBG1 | c.7C>A p.R3S | Missense Mutation (SNP) | VAF 56/348 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV51904470; called by muse, mutect2, varscan2
- AGA | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 97/752 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.214); catalogued as rs925345330, COSV52805940; called by muse, mutect2, varscan2
- ALPK1 | c.842C>G p.A281G | Missense Mutation (SNP) | VAF 78/411 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); catalogued as rs763792725, COSV51583381; called by muse, mutect2, varscan2
- ALPK2 | c.5566T>A p.Y1856N | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64491483; called by muse, mutect2, varscan2
- ANKRD30A | c.812C>A p.T271N (on ENST00000611781; = p.T215N on NM_052997.2) | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV64606951; called by muse, mutect2
- ANKRD30A | c.1656C>G p.F552L (on ENST00000611781; = p.F496L on NM_052997.2) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.827); catalogued as COSV64606962, COSV64613911, COSV64618406; called by muse, mutect2, varscan2
- ARHGAP6 | c.1271A>G p.H424R | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV57293615; called by muse, mutect2, varscan2
- ATPSCKMT | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 82/296 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs367602123; called by muse, mutect2, varscan2
- BCDIN3D | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 17/343 reads (5%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.994); catalogued as rs1555154963, COSV61702309, COSV61702536; called by muse, mutect2
- BIVM-ERCC5 | c.2165A>G p.D722G | Missense Mutation (SNP) | VAF 46/221 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.085); catalogued as COSV63244488; called by muse, mutect2, varscan2
- C1orf112 | c.1495A>G p.I499V | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53677502; called by muse, mutect2
- C2orf78 | c.807C>A p.Y269* | Nonsense Mutation (SNP) | VAF 35/277 reads (13%) | catalogued as COSV68516899; called by muse, mutect2, varscan2
- CACNA1C | c.4382T>A p.M1461K | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV59705657; called by muse, mutect2
- CCDC150 | c.1440G>C p.E480D | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV55873051; called by muse, mutect2, varscan2
- CCR10 | c.539G>C p.S180T | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.243); catalogued as COSV52848886; called by muse, mutect2, varscan2
- CDH4 | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.737); catalogued as COSV64646922, COSV64662424; called by muse, mutect2
- CDKN2A | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.02); catalogued as rs45476696, CM1414341, CM156717, CS108038, CS972842, COSV58690140, COSV58729212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD1L | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 21/113 reads (19%) | catalogued as COSV63613300; called by muse, mutect2, varscan2
- CLEC6A | c.52C>A p.L18M | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); catalogued as COSV65986922; called by muse, mutect2, varscan2
- CRACD | c.1275C>A p.D425E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV51717945; called by muse, mutect2, varscan2
- CRTAC1 | c.1124G>T p.R375L | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs770267639, COSV53999139; called by muse, mutect2, varscan2
- CTTNBP2 | c.2758G>T p.A920S | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs147958874, COSV50392789; called by muse, mutect2, varscan2
- CYLD | c.2241+1G>T p.X747_splice | Splice Site (SNP) | VAF 25/142 reads (18%) | catalogued as COSV61093645; called by muse, mutect2, varscan2
- DCAF5 | c.1526G>T p.R509L | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as COSV58459382; called by muse, mutect2, varscan2
- DCLRE1C | c.756G>C p.Q252H (on ENST00000378278 / NM_001350965.2; = p.Q137H on NM_022487.4) | Missense Mutation (SNP) | VAF 60/313 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs1249898599, COSV63182307; called by muse, mutect2, varscan2
- DDX58 | c.1062C>A p.N354K | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as COSV65882710; called by muse, mutect2, varscan2
- DPYD | c.1097G>T p.G366V | Missense Mutation (SNP) | VAF 47/348 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs752985272, CM052849, COSV64593648; called by muse, mutect2, varscan2
- DPYD | c.1096G>A p.G366S | Missense Mutation (SNP) | VAF 45/347 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.654); catalogued as COSV64593649, COSV64616260; called by muse, mutect2, varscan2
- DSTYK | c.2541G>T p.K847N | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV65685906; called by muse, mutect2, varscan2
- EPB41L3 | c.2620G>A p.A874T | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.211); catalogued as COSV59448138; called by muse, mutect2, varscan2
- EPG5 | c.7333C>G p.R2445G | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as CM163403, COSV99957314, COSV99957326; called by mutect2, varscan2
- EZH2 | c.1642C>G p.Q548E (on ENST00000460911 / NM_001203247.2; = p.Q553E on NM_004456.5) | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV57449326, COSV57450222; called by muse, mutect2
- GALNT3 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as COSV67061558; called by muse, mutect2, varscan2
- GALNTL5 | c.909G>C p.R303= | Splice Region (SNP) | VAF 43/344 reads (13%) | catalogued as COSV67179632; called by muse, mutect2, varscan2
- GAP43 | c.224C>A p.A75D | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV100525230, COSV59343119; called by muse, mutect2, varscan2
- GCDH | c.557G>C p.S186T | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs763739291, COSV53366054; ClinVar: uncertain significance; called by muse, mutect2
- HACE1 | c.2717A>G p.Y906C | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53501056; called by muse, mutect2, varscan2
- IFT57 | c.608A>T p.E203V | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as COSV52708813; called by muse, mutect2
- KAT7 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV52013610; called by muse, mutect2
- KCNA4 | c.610G>C p.D204H | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV60251286, COSV60251420; called by muse, mutect2, varscan2
- KIAA0319 | c.1993G>T p.G665C | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65497263; called by muse, mutect2, varscan2
- KRI1 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV57264080; called by muse, mutect2
- LCT | c.5234T>A p.I1745N | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51546232; called by muse, mutect2, varscan2
- LINGO1 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62436506; called by muse, mutect2, varscan2
- LRBA | c.4027G>T p.D1343Y | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100841896, COSV63952041; called by muse, varscan2
- MACROH2A1 | c.28T>C p.S10P | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV56894049; called by muse, mutect2, varscan2
- MAD2L1 | c.583A>G p.S195G | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV56636733; called by muse, mutect2
- MAGEE2 | c.452C>A p.A151D | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.354); catalogued as COSV64897492; called by muse, mutect2, varscan2
- MARCO | c.1519G>T p.D507Y | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV59053160; called by muse, mutect2, varscan2
- MCHR2 | c.817G>T p.V273L | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV56001124; called by muse, mutect2, varscan2
- MUC4 | c.12739A>G p.T4247A | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.028); catalogued as COSV57773033; called by muse, varscan2
- MYEOV | c.49C>G p.L17V | Missense Mutation (SNP) | VAF 228/354 reads (64%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.959); catalogued as COSV58293728; called by muse, mutect2, varscan2
- NEXMIF | c.4495T>A p.F1499I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.048); catalogued as COSV50024375; called by muse, mutect2, varscan2
- OR1C1 | c.463C>A p.H155N | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.649); catalogued as COSV68715482, COSV68715552; called by muse, mutect2, varscan2
- OR1L4 | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52340069; called by muse, varscan2
- OR2Z1 | c.740T>C p.V247A | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.309); catalogued as COSV60691992; called by muse, mutect2, varscan2
- OR5D18 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 70/369 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV61736623, COSV61736716; called by muse, mutect2, varscan2
- OR5I1 | c.767C>G p.T256S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV56886059; called by muse, mutect2, varscan2
- OR7E24 | c.311A>C p.Q104P | Missense Mutation (SNP) | VAF 6/160 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV71702160; called by muse, mutect2
- OS9 | c.1898C>T p.A633V | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.031); catalogued as COSV57727413; called by muse, mutect2, varscan2
- OTOF | c.4433A>G p.Y1478C (on ENST00000272371 / NM_194248.3; = p.Y711C on NM_004802.4) | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.371); catalogued as rs1385217285, COSV55499221; called by muse, mutect2, varscan2
- PATE1 | c.362T>A p.L121Q | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV59824264; called by muse, mutect2, varscan2
- PAX3 | c.1093A>T p.S365C | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); catalogued as COSV60587084; called by muse, mutect2, varscan2
- PCCB | c.572C>G p.P191R | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52444121; called by muse, mutect2, varscan2
- PCDHB1 | c.2173A>G p.T725A | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV60630062; called by muse, mutect2, varscan2
- PHTF1 | c.1089C>A p.N363K | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV63367096; called by muse, mutect2, varscan2
- PIKFYVE | c.3452T>A p.M1151K | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV52238885; called by muse, mutect2
- POU6F2 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV101302671; called by muse, varscan2
- PREB | c.293A>G p.H98R | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV53205278; called by muse, mutect2, varscan2
- RALGAPA1 | c.3689C>T p.P1230L | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51879253; called by muse, mutect2
- RIMKLB | c.1114A>C p.N372H | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV55235951; called by muse, mutect2, varscan2
- RNF13 | c.728G>A p.C243Y | Missense Mutation (SNP) | VAF 24/648 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53523057; called by muse, mutect2
- SETBP1 | c.2848G>A p.D950N | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV56316627; called by muse, mutect2, varscan2
- SF3B2 | c.2397G>T p.M799I | Missense Mutation (SNP) | VAF 51/334 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.061); catalogued as COSV57697029; called by muse, mutect2, varscan2
- SHC4 | c.72G>T p.M24I | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV60110482; called by muse, mutect2, varscan2
- SIGLEC14 | c.702T>C p.Y234= | Splice Region (SNP) | VAF 16/262 reads (6%) | catalogued as COSV55778455; called by muse, mutect2
- SIGLEC9 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 33/331 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.519); catalogued as COSV51583010, COSV51583338; called by muse, mutect2
- SLAMF1 | c.739G>A p.G247S | Missense Mutation (SNP) | VAF 68/447 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV52498353; called by muse, mutect2, varscan2
- SLC36A2 | c.553A>T p.N185Y | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.396); catalogued as COSV58862628; called by muse, mutect2, varscan2
- SLITRK3 | c.1019G>T p.R340L | Missense Mutation (SNP) | VAF 218/842 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53846718, COSV53850770; called by muse, mutect2, varscan2
- SOHLH1 | c.929G>C p.G310A | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.118); catalogued as COSV53681072; called by muse, varscan2
- SOX5 | c.1622G>C p.R541T | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58623545; called by muse, mutect2
- SPATA21 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs542699732, COSV59186039; called by muse, mutect2, varscan2
- SPHKAP | c.249C>A p.V83= | Splice Region (SNP) | VAF 29/189 reads (15%) | catalogued as rs1268106360, COSV60872717; called by muse, mutect2, varscan2
- STAT4 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.657); catalogued as COSV61828808; called by muse, mutect2
- TBX22 | c.326G>C p.G109A | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64785354; called by muse, mutect2, varscan2
- THUMPD3 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61505752; called by muse, mutect2, varscan2
- TP53 | c.383del p.P128Lfs*42 | Frame Shift Del (DEL) | VAF 18/90 reads (20%) | catalogued as COSV53283607; called by mutect2, pindel, varscan2
- TRABD2A | c.179A>G p.H60R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs749481202, COSV59102348; called by muse, mutect2, varscan2
- UBE2Q1 | c.1124C>G p.A375G | Missense Mutation (SNP) | VAF 50/314 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52724384; called by muse, varscan2
- UBE2Q1 | c.1123G>T p.A375S | Missense Mutation (SNP) | VAF 52/317 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV52724392; called by muse, varscan2
- USH2A | c.9740-1G>T p.X3247_splice | Splice Site (SNP) | VAF 9/58 reads (16%) | catalogued as COSV56346800; called by muse, mutect2
- VWA8 | c.4495G>A p.V1499I | Missense Mutation (SNP) | VAF 68/383 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.192); catalogued as COSV64994849; called by muse, mutect2, varscan2
- WDR7 | c.1931C>G p.A644G | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV54350305, COSV54352949; called by muse, mutect2, varscan2
- WDR75 | c.1402G>A p.G468S | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as COSV59105038; called by muse, mutect2, varscan2
- YTHDF2 | c.1721G>C p.R574P | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV65722995; called by muse, mutect2, varscan2
- ZBP1 | c.310C>G p.Q104E | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs1454983833, COSV59060936; called by muse, mutect2, varscan2
- ZFHX4 | c.8383C>A p.Q2795K | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.754); catalogued as rs761305789, COSV50644732; called by muse, mutect2, varscan2
- ZNF107 | c.1152T>G p.Y384* | Nonsense Mutation (SNP) | VAF 13/93 reads (14%) | catalogued as COSV61327464, COSV61327531; called by muse, mutect2, varscan2
- ARHGAP32 | c.40_41del p.S14Cfs*7 | Frame Shift Del (DEL) | VAF 93/482 reads (19%) | called by mutect2, pindel, varscan2
- IGHV3-35 | c.125C>A p.A42E | Missense Mutation (SNP) | VAF 18/305 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.517); called by muse, mutect2
- MYOM2 | c.1149_1150del p.G384Cfs*27 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- RPS3A | c.563+3_563+6del p.X188_splice | Splice Site (DEL) | VAF 6/51 reads (12%) | called by mutect2, pindel
- TRAF3 | c.1078del p.R360Afs*2 | Frame Shift Del (DEL) | VAF 32/199 reads (16%) | called by mutect2, pindel, varscan2
- ADA2 | c.198C>G p.L66= | Silent (SNP) | VAF 21/148 reads (14%) | catalogued as COSV52830805, COSV99375882; called by muse, mutect2, varscan2
- ALG3 | c.540G>A p.V180= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs369032582; called by muse, mutect2, varscan2
- C1orf74 | c.189A>G p.A63= | Silent (SNP) | VAF 30/138 reads (22%) | catalogued as COSV50551247; called by muse, mutect2, varscan2
- C2CD6 | c.888G>C p.L296= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV53792673; called by muse, mutect2, varscan2
- CA8 | c.696C>A p.T232= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as COSV58771260; called by muse, mutect2
- CD86 | c.609G>A p.L203= (on ENST00000330540 / NM_175862.5; = p.L197= on NM_006889.4) | Silent (SNP) | VAF 77/488 reads (16%) | catalogued as COSV52605874; called by muse, mutect2, varscan2
- DOCK5 | c.4500G>A p.K1500= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs922287260, COSV52398236; called by muse, mutect2, varscan2
- EIF3A | c.3987A>T p.R1329= | Silent (SNP) | VAF 33/182 reads (18%) | catalogued as COSV60775159; called by muse, mutect2, varscan2
- F9 | c.1077C>A p.V359= | Silent (SNP) | VAF 50/135 reads (37%) | catalogued as CD890150, COSV54379422; called by muse, mutect2, varscan2
- GAP43 | c.225C>G p.A75= | Silent (SNP) | VAF 24/160 reads (15%) | catalogued as COSV59343132; called by muse, mutect2, varscan2
- MARCHF6 | c.1128T>C p.S376= | Silent (SNP) | VAF 22/662 reads (3%) | catalogued as COSV56879757; called by muse, mutect2
- MIEF1 | c.423T>G p.T141= | Silent (SNP) | VAF 53/148 reads (36%) | catalogued as COSV57477991; called by muse, mutect2, varscan2
- MUC16 | c.34893G>T p.V11631= | Silent (SNP) | VAF 39/281 reads (14%) | catalogued as COSV67454784, COSV67458678; called by muse, mutect2, varscan2
- OR1L4 | c.852C>A p.P284= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as COSV52340084; called by muse, varscan2
- OR3A2 | c.744C>A p.S248= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV101375067, COSV68695009; called by muse, mutect2, varscan2
- OR52H1 | c.657C>G p.S219= (on ENST00000322653; = p.S225= on NM_001005289.1) | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV100497357, COSV59504797, COSV59505110; called by muse, mutect2, varscan2
- OR56A3 | c.699G>A p.K233= | Silent (SNP) | VAF 44/432 reads (10%) | catalogued as COSV61568714; called by muse, mutect2, varscan2
- PCARE | c.3802C>A p.R1268= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV59053887; called by muse, mutect2, varscan2
- PRKAR1B | c.273G>T p.V91= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as COSV64318176; called by muse, mutect2, varscan2
- QPCT | c.375C>T p.S125= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as COSV58119374; called by muse, mutect2, varscan2
- SALL1 | c.192C>T p.N64= | Silent (SNP) | VAF 73/395 reads (18%) | catalogued as COSV51755232; called by muse, mutect2, varscan2
- SEC24B | c.1296A>G p.E432= | Silent (SNP) | VAF 55/251 reads (22%) | catalogued as COSV54496985; called by muse, mutect2, varscan2
- SLC13A3 | c.1539C>G p.G513= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV51713425; called by muse, mutect2
- SLC4A3 | c.3244C>A p.R1082= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV56092573, COSV56098623; called by muse, mutect2, varscan2
- SNAI2 | c.213T>C p.N71= | Silent (SNP) | VAF 70/383 reads (18%) | catalogued as COSV50078779, COSV99195025; called by muse, mutect2, varscan2
- SPATA5 | c.2427G>A p.Q809= | Silent (SNP) | VAF 43/212 reads (20%) | catalogued as rs751207647, COSV56773713; called by muse, mutect2, varscan2
- ST13 | c.1107G>T p.A369= | Silent (SNP) | VAF 176/713 reads (25%) | catalogued as COSV53421200, COSV53421984; called by muse, mutect2, varscan2
- SYNE1 | c.267G>T p.V89= | Silent (SNP) | VAF 62/374 reads (17%) | catalogued as COSV54940064; called by muse, mutect2, varscan2
- TBXAS1 | c.963T>G p.P321= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV54942848; called by muse, mutect2, varscan2
- THEG | c.645T>A p.P215= | Silent (SNP) | VAF 63/370 reads (17%) | catalogued as COSV61073501; called by muse, mutect2, varscan2
- TMEM94 | c.3540C>A p.I1180= | Silent (SNP) | VAF 13/267 reads (5%) | catalogued as COSV58594175; called by muse, mutect2
- TRIM50 | c.771G>T p.R257= | Silent (SNP) | VAF 9/108 reads (8%) | called by muse, mutect2
- TRPM2 | c.2412C>A p.L804= | Silent (SNP) | VAF 61/892 reads (7%) | catalogued as COSV55967696; called by muse, mutect2
- WDR62 | c.210C>A p.A70= | Silent (SNP) | VAF 6/97 reads (6%) | catalogued as COSV53077894; called by muse, mutect2
- ZNF100 | c.543A>T p.P181= | Silent (SNP) | VAF 39/235 reads (17%) | catalogued as COSV59746925; called by muse, mutect2, varscan2
- DCHS2 | n.1060G>T | RNA (SNP) | VAF 14/197 reads (7%) | catalogued as COSV59721577; called by muse, mutect2
- USH1C | c.1646+1162C>A | Intron (SNP) | VAF 54/465 reads (12%) | catalogued as COSV99140132; called by muse, mutect2, varscan2
